Somatic mutation profile of tumor specimen TCGA-FU-A23K-01A (aliquot TCGA-FU-A23K-01A-11D-A16O-08) from TCGA case TCGA-FU-A23K, project TCGA-CESC (Cervical Squamous Cell Carcinoma and Endocervical Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Basaloid squamous cell carcinoma; Tissue or organ of origin: Cervix uteri; FIGO stage: Stage IIIB; Tumor grade: G3; Age at diagnosis: 28.9 years (10,551 days).
Specimen TCGA-FU-A23K-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 4b8fc5d9-924e-4643-828d-92dde35fc510.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-FU-A23K-10A (Blood Derived Normal), aliquot TCGA-FU-A23K-10A-01D-A16O-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/6cb2661a-be16-40ce-adb1-80d62b9d7c75

The open-access MAF lists 116 somatic variants for this specimen: 79 protein-altering or splice-affecting, 33 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 72, Silent 33, Nonsense Mutation 6, Intron 2, 3'UTR 1, Splice Site 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ASS1 | c.1088G>A p.R363Q | Missense Mutation (SNP) | VAF 8/27 reads (30%) | SIFT deleterious (0.04); PolyPhen benign (0.164); catalogued as rs771937610, CM031630, CM940129, COSV61689902; ClinVar: pathogenic / uncertain significance; called by muse, mutect2, varscan2
- PIK3CA | c.1031T>G p.V344G | Missense Mutation (SNP) | VAF 26/96 reads (27%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.957); catalogued as rs1057519941, COSV55876054, COSV55895486, COSV55974473; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- PTEN | c.635-1G>A p.X212_splice | Splice Site (SNP) | VAF 46/66 reads (70%) | hotspot (GDC flag); catalogued as rs876661024, CS090867, CS993675, COSV64289221, COSV64292432, COSV64296169; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ABCA12 | c.6037C>T p.Q2013* (on ENST00000272895 / NM_173076.3; = p.Q1695* on NM_015657.3) | Nonsense Mutation (SNP) | VAF 22/73 reads (30%) | catalogued as COSV55965524; called by muse, mutect2, varscan2
- ABCD2 | c.181G>C p.E61Q | Missense Mutation (SNP) | VAF 37/158 reads (23%) | SIFT tolerated (0.29); PolyPhen benign (0.037); catalogued as COSV58052852; called by muse, mutect2, varscan2
- AHNAK2 | c.17230G>C p.E5744Q | Missense Mutation (SNP) | VAF 10/36 reads (28%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.964); catalogued as COSV60920653; called by muse, mutect2, varscan2
- AHNAK2 | c.15968G>C p.G5323A | Missense Mutation (SNP) | VAF 12/42 reads (29%) | SIFT tolerated (0.2); PolyPhen benign (0.023); catalogued as COSV60920677; called by muse, mutect2, varscan2
- AHNAK2 | c.15766G>A p.E5256K | Missense Mutation (SNP) | VAF 75/270 reads (28%) | SIFT tolerated (0.65); PolyPhen benign (0.003); catalogued as rs760136978, COSV60920688; called by muse, mutect2, varscan2
- AKR1C8P | c.361G>A p.V121I | Missense Mutation (SNP) | VAF 12/26 reads (46%) | SIFT tolerated (0.21); PolyPhen benign (0.005); catalogued as rs1554792796; called by muse, mutect2, varscan2
- ALS2CL | c.2143G>C p.E715Q | Missense Mutation (SNP) | VAF 21/56 reads (38%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.522); catalogued as COSV59672238; called by muse, mutect2, varscan2
- ANGPT4 | c.731T>C p.V244A | Missense Mutation (SNP) | VAF 5/27 reads (19%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV67922118; called by muse, mutect2
- APC | c.4630G>C p.E1544Q | Missense Mutation (SNP) | VAF 22/73 reads (30%) | SIFT tolerated (0.26); PolyPhen benign (0.007); catalogued as COSV57327947, COSV57331833, COSV57342321, COSV57357142; called by muse, mutect2, varscan2
- ARHGAP31 | c.3823G>T p.V1275L | Missense Mutation (SNP) | VAF 17/40 reads (43%) | SIFT tolerated (0.5); PolyPhen benign (0); catalogued as COSV51795503; called by muse, mutect2, varscan2
- AVPR1B | c.1128C>G p.H376Q | Missense Mutation (SNP) | VAF 6/20 reads (30%) | SIFT tolerated (0.42); PolyPhen benign (0.015); catalogued as COSV65638307; called by muse, mutect2, varscan2
- BARHL2 | c.485C>T p.T162I | Missense Mutation (SNP) | VAF 6/14 reads (43%) | SIFT deleterious (0.04); PolyPhen benign (0.425); catalogued as COSV64981575; called by muse, mutect2, varscan2
- CA14 | c.972G>C p.K324N | Missense Mutation (SNP) | VAF 11/39 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as COSV52529821; called by muse, mutect2, varscan2
- CA2 | c.214G>A p.D72N | Missense Mutation (SNP) | VAF 12/40 reads (30%) | SIFT deleterious (0); PolyPhen benign (0.023); catalogued as COSV53407434; called by muse, mutect2, varscan2
- CAT | c.988G>A p.E330K | Missense Mutation (SNP) | VAF 24/71 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53811899; called by muse, mutect2, varscan2
- CCDC88A | c.3412G>A p.E1138K | Missense Mutation (SNP) | VAF 34/106 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV55064924; called by muse, mutect2, varscan2
- CD180 | c.1187C>T p.S396F | Missense Mutation (SNP) | VAF 44/147 reads (30%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.463); catalogued as COSV56518770; called by muse, mutect2, varscan2
- CD44 | c.1521G>C p.Q507H | Missense Mutation (SNP) | VAF 40/126 reads (32%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.707); catalogued as COSV53530130; called by muse, mutect2, varscan2
- CDH7 | c.541G>A p.D181N | Missense Mutation (SNP) | VAF 32/93 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV59888805; called by muse, mutect2, varscan2
- CHRNA3 | c.713G>A p.R238Q | Missense Mutation (SNP) | VAF 10/55 reads (18%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); catalogued as rs149559299; called by muse, mutect2, varscan2
- CLEC14A | c.832G>C p.E278Q | Missense Mutation (SNP) | VAF 47/117 reads (40%) | SIFT tolerated (0.6); PolyPhen benign (0.006); catalogued as COSV60563223, COSV60563655; called by muse, mutect2, varscan2
- CRB1 | c.1094G>A p.R365H | Missense Mutation (SNP) | VAF 24/70 reads (34%) | SIFT tolerated (0.69); PolyPhen benign (0.01); catalogued as rs777528044, COSV66343813, COSV66350679; called by muse, mutect2, varscan2
- CREBBP | c.182C>T p.P61L | Missense Mutation (SNP) | VAF 26/76 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.975); catalogued as COSV52129848; called by muse, mutect2, varscan2
- CRTC2 | c.228G>C p.Q76H | Missense Mutation (SNP) | VAF 15/43 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV57843950; called by muse, mutect2, varscan2
- CRX | c.455C>T p.S152F | Missense Mutation (SNP) | VAF 17/65 reads (26%) | SIFT tolerated (0.2); PolyPhen benign (0.227); catalogued as CM083614, COSV55759139; called by muse, mutect2, varscan2
- CTCFL | c.112G>C p.E38Q | Missense Mutation (SNP) | VAF 107/501 reads (21%) | SIFT tolerated (0.12); PolyPhen benign (0.062); catalogued as COSV54776237; called by muse, mutect2, varscan2
- DAAM1 | c.1051G>C p.E351Q | Missense Mutation (SNP) | VAF 12/58 reads (21%) | SIFT deleterious (0.01); PolyPhen benign (0.404); catalogued as COSV62837620; called by muse, mutect2, varscan2
- DLGAP3 | c.1177C>T p.R393W | Missense Mutation (SNP) | VAF 36/112 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as rs768529358, COSV52395331; called by muse, mutect2, varscan2
- DPP9 | c.809T>A p.L270H (on ENST00000598800; = p.L299H on NM_139159.5) | Missense Mutation (SNP) | VAF 9/26 reads (35%) | SIFT tolerated (0.54); PolyPhen benign (0.003); catalogued as COSV53592402; called by muse, mutect2, varscan2
- ECHDC1 | c.870G>A p.W290* (on ENST00000531967 / NM_001139510.1; = p.W284* on NM_001002030.2) | Nonsense Mutation (SNP) | VAF 58/94 reads (62%) | catalogued as COSV58933067; called by muse, mutect2, varscan2
- FGFR1OP2 | c.571G>A p.E191K | Missense Mutation (SNP) | VAF 17/45 reads (38%) | SIFT deleterious (0.02); PolyPhen benign (0.062); catalogued as COSV57587519; called by muse, mutect2, varscan2
- FOXC2 | c.1354G>A p.E452K | Missense Mutation (SNP) | VAF 19/47 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV57444747; called by muse, mutect2, varscan2
- GABRB3 | c.835G>A p.G279R | Missense Mutation (SNP) | VAF 5/33 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54671620; called by muse, mutect2
- HGFAC | c.336C>G p.F112L | Missense Mutation (SNP) | VAF 15/33 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.936); catalogued as COSV58754090; called by muse, mutect2, varscan2
- HOMER2 | c.303G>C p.E101D | Missense Mutation (SNP) | VAF 19/54 reads (35%) | SIFT tolerated (0.11); PolyPhen benign (0.007); catalogued as COSV58486988; called by muse, mutect2, varscan2
- HOXA4 | c.739G>A p.E247K | Missense Mutation (SNP) | VAF 28/112 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57827465; called by muse, mutect2, varscan2
- INO80D | c.1009G>C p.E337Q | Missense Mutation (SNP) | VAF 24/71 reads (34%) | SIFT deleterious (0.01); PolyPhen benign (0.033); catalogued as COSV68959423; called by muse, mutect2, varscan2
- IRF2BP1 | c.65G>C p.W22S | Missense Mutation (SNP) | VAF 9/18 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100138944, COSV56194144; called by muse, mutect2, varscan2
- LGALS12 | c.169G>A p.D57N | Missense Mutation (SNP) | VAF 9/56 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.985); catalogued as COSV55371141; called by muse, mutect2, varscan2
- LYST | c.3238G>C p.A1080P | Missense Mutation (SNP) | VAF 26/95 reads (27%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.003); catalogued as COSV67709386; called by muse, mutect2, varscan2
- LYST | c.2863G>C p.E955Q | Missense Mutation (SNP) | VAF 39/133 reads (29%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.424); catalogued as COSV67709394; called by muse, mutect2, varscan2
- MAP3K4 | c.710C>T p.S237L | Missense Mutation (SNP) | VAF 17/21 reads (81%) | SIFT deleterious (0); PolyPhen possibly damaging (0.905); catalogued as COSV62335593, COSV62338386; called by muse, mutect2, varscan2
- MAST1 | c.3103G>C p.E1035Q | Missense Mutation (SNP) | VAF 21/92 reads (23%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.999); catalogued as COSV52249725; called by muse, mutect2, varscan2
- MFAP3L | c.286G>A p.E96K | Missense Mutation (SNP) | VAF 90/167 reads (54%) | SIFT tolerated (0.8); PolyPhen benign (0); catalogued as rs763467684, COSV64372427; called by muse, mutect2, varscan2
- MGAM | c.55C>A p.L19I | Missense Mutation (SNP) | VAF 8/27 reads (30%) | SIFT tolerated (0.07); PolyPhen benign (0.005); catalogued as COSV71885679; called by muse, mutect2, varscan2
- MKI67 | c.979C>A p.Q327K | Missense Mutation (SNP) | VAF 73/112 reads (65%) | SIFT tolerated (0.09); PolyPhen benign (0.354); catalogued as COSV64075346; called by muse, mutect2, varscan2
- MXRA5 | c.7216C>T p.Q2406* | Nonsense Mutation (SNP) | VAF 44/145 reads (30%) | catalogued as COSV54240680; called by muse, mutect2, varscan2
- MYH6 | c.4249G>C p.E1417Q | Missense Mutation (SNP) | VAF 44/109 reads (40%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs1060501426, COSV62452183; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- NCKAP1 | c.1831C>T p.R611* | Nonsense Mutation (SNP) | VAF 17/61 reads (28%) | catalogued as COSV62940882, COSV62941047; called by muse, mutect2, varscan2
- PDE1C | c.623C>T p.A208V | Missense Mutation (SNP) | VAF 22/61 reads (36%) | SIFT tolerated (0.32); PolyPhen benign (0.084); catalogued as rs1363381812, COSV58518771; called by muse, mutect2, varscan2
- PEX12 | c.178G>C p.D60H | Missense Mutation (SNP) | VAF 90/235 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56778469; called by muse, mutect2, varscan2
- PIGN | c.2631C>G p.F877L | Missense Mutation (SNP) | VAF 5/24 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.917); catalogued as COSV100716267, COSV62950286; called by muse, mutect2
- POU4F1 | c.1000G>C p.E334Q | Missense Mutation (SNP) | VAF 9/23 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.65); catalogued as rs555673947, COSV101020540; called by muse, mutect2, varscan2
- PYGB | c.629C>G p.T210S | Missense Mutation (SNP) | VAF 105/228 reads (46%) | SIFT tolerated (0.4); PolyPhen benign (0); catalogued as COSV53820171; called by muse, mutect2, varscan2
- RLF | c.5647C>T p.R1883W | Missense Mutation (SNP) | VAF 28/90 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV65652250; called by muse, mutect2, varscan2
- RNF150 | c.11C>T p.S4F | Missense Mutation (SNP) | VAF 10/50 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.99); catalogued as rs368156046; called by muse, mutect2, varscan2
- SCO1 | c.73C>G p.R25G | Missense Mutation (SNP) | VAF 8/26 reads (31%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.07); catalogued as COSV55135722, COSV99703635; called by muse, mutect2, varscan2
- SERPINE2 | c.243G>A p.M81I | Missense Mutation (SNP) | VAF 17/66 reads (26%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.718); catalogued as COSV51458578; called by muse, mutect2
- SLC44A4 | c.2023G>C p.E675Q | Missense Mutation (SNP) | VAF 36/51 reads (71%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1214055086, COSV57668005; called by muse, mutect2, varscan2
- SORCS3 | c.2660G>A p.G887E | Missense Mutation (SNP) | VAF 24/67 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV63796251; called by muse, mutect2, varscan2
- SPAG4 | c.452G>A p.G151E | Missense Mutation (SNP) | VAF 17/29 reads (59%) | SIFT tolerated (0.09); PolyPhen benign (0.348); catalogued as rs375034562; called by muse, mutect2, varscan2
- SPAG4 | c.907G>C p.E303Q | Missense Mutation (SNP) | VAF 72/116 reads (62%) | SIFT tolerated (0.36); PolyPhen probably damaging (0.945); catalogued as COSV65330719, COSV65330755; called by muse, varscan2
- SPTY2D1 | c.662G>T p.G221V | Missense Mutation (SNP) | VAF 60/219 reads (27%) | SIFT tolerated (0.28); PolyPhen benign (0); catalogued as COSV60474471; called by muse, mutect2, varscan2
- STT3A | c.224G>A p.R75Q | Missense Mutation (SNP) | VAF 11/34 reads (32%) | SIFT deleterious (0.01); PolyPhen benign (0.206); catalogued as rs540684198, COSV67064320; called by muse, mutect2, varscan2
- SYT12 | c.42G>C p.K14N | Missense Mutation (SNP) | VAF 14/49 reads (29%) | SIFT tolerated, low confidence (0.25); PolyPhen benign (0.01); catalogued as COSV67354382; called by muse, mutect2, varscan2
- TAF9B | c.595C>T p.P199S | Missense Mutation (SNP) | VAF 82/198 reads (41%) | SIFT tolerated (0.32); PolyPhen probably damaging (0.968); catalogued as COSV59371620; called by muse, mutect2, varscan2
- TAP2 | c.94C>T p.P32S | Missense Mutation (SNP) | VAF 13/81 reads (16%) | SIFT deleterious (0.02); PolyPhen benign (0.103); catalogued as COSV66487587; called by muse, mutect2, varscan2
- TCL1B | c.112C>T p.R38W | Missense Mutation (SNP) | VAF 15/48 reads (31%) | SIFT deleterious (0.01); PolyPhen benign (0.015); catalogued as rs75572239, COSV61552122; called by muse, mutect2, varscan2
- TMEM259 | c.537C>G p.F179L | Missense Mutation (SNP) | VAF 24/78 reads (31%) | SIFT tolerated (0.41); PolyPhen benign (0); catalogued as COSV52261459; called by muse, mutect2, varscan2
- TTN | c.5422G>A p.E1808K (on ENST00000591111; = p.E1762K on NM_003319.4) | Missense Mutation (SNP) | VAF 58/153 reads (38%) | PolyPhen benign (0.169); catalogued as COSV59875682; called by muse, mutect2, varscan2
- TUBA8 | c.593C>G p.S198* | Nonsense Mutation (SNP) | VAF 57/168 reads (34%) | catalogued as COSV57813408; called by muse, mutect2, varscan2
- UBR4 | c.5711C>G p.S1904C | Missense Mutation (SNP) | VAF 27/114 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV64393051; called by muse, mutect2, varscan2
- UMODL1 | c.1498C>T p.R500W | Missense Mutation (SNP) | VAF 21/63 reads (33%) | SIFT deleterious (0); PolyPhen benign (0.028); catalogued as rs776693385, COSV61160833; called by muse, mutect2, varscan2
- USP26 | c.1150C>T p.H384Y | Missense Mutation (SNP) | VAF 44/189 reads (23%) | SIFT tolerated (0.08); PolyPhen probably damaging (1); catalogued as COSV100896585, COSV63709074; called by muse, mutect2, varscan2
- ZFHX3 | c.7783C>T p.Q2595* | Nonsense Mutation (SNP) | VAF 48/151 reads (32%) | catalogued as COSV51724466, COSV99195748; called by muse, mutect2, varscan2
- ZSCAN22 | c.399G>C p.K133N | Missense Mutation (SNP) | VAF 8/14 reads (57%) | SIFT deleterious (0.05); PolyPhen benign (0.329); catalogued as COSV61638699; called by muse, mutect2, varscan2
- ALDH4A1 | c.966C>T p.F322= | Silent (SNP) | VAF 13/37 reads (35%) | catalogued as rs150927009, COSV51893029; called by muse, mutect2, varscan2
- AMER1 | c.177C>G p.L59= | Silent (SNP) | VAF 29/150 reads (19%) | catalogued as COSV57662977; called by muse, mutect2, varscan2
- ATG12 | c.372C>T p.G124= | Silent (SNP) | VAF 4/24 reads (17%) | catalogued as COSV57243398, COSV99174621; called by muse, mutect2
- ATP6V1E2 | c.9G>C p.L3= | Silent (SNP) | VAF 15/48 reads (31%) | catalogued as rs752416922, COSV60576273; called by muse, mutect2, varscan2
- BARHL2 | c.486C>T p.T162= | Silent (SNP) | VAF 7/15 reads (47%) | catalogued as rs1353473623, COSV64981563; called by muse, mutect2, varscan2
- C22orf31 | c.372C>T p.F124= | Silent (SNP) | VAF 26/97 reads (27%) | catalogued as rs552864793, COSV53310806; called by muse, mutect2, varscan2
- CAMSAP3 | c.1257C>T p.V419= | Silent (SNP) | VAF 4/15 reads (27%) | catalogued as rs1041940749, COSV50330984; called by muse, mutect2, varscan2
- CD36 | c.576C>T p.Y192= | Silent (SNP) | VAF 36/121 reads (30%) | catalogued as COSV59212691; called by muse, mutect2, varscan2
- CFAP57 | c.1524G>C p.L508= | Silent (SNP) | VAF 38/122 reads (31%) | catalogued as COSV63016639, COSV63016747; called by muse, mutect2
- CTCFL | c.300G>A p.L100= | Silent (SNP) | VAF 25/132 reads (19%) | catalogued as COSV54776220; called by muse, mutect2, varscan2
- DPP9 | c.810C>G p.L270= (on ENST00000598800; = p.L299= on NM_139159.5) | Silent (SNP) | VAF 9/26 reads (35%) | catalogued as COSV53592381; called by muse, mutect2, varscan2
- ELOA2 | c.616C>T p.L206= | Silent (SNP) | VAF 14/32 reads (44%) | catalogued as COSV55302273; called by muse, mutect2, varscan2
- EPX | c.1146C>A p.P382= | Silent (SNP) | VAF 16/48 reads (33%) | catalogued as COSV56597299; called by muse, mutect2, varscan2
- GABRB3 | c.120G>A p.T40= | Silent (SNP) | VAF 7/24 reads (29%) | catalogued as COSV100160918, COSV54669299; called by muse, mutect2, varscan2
- GFRA3 | c.1065C>G p.L355= | Silent (SNP) | VAF 5/14 reads (36%) | catalogued as COSV51229326; called by muse, mutect2, varscan2
- H2BC13 | c.222C>A p.I74= | Silent (SNP) | VAF 158/218 reads (72%) | catalogued as COSV62440473, COSV62440942, COSV62441214; called by muse, mutect2, varscan2
- IGFL2 | c.165C>T p.D55= (on ENST00000377693 / NM_001135113.2; = p.D66= on NM_001002915.2) | Silent (SNP) | VAF 67/259 reads (26%) | catalogued as rs199772350, COSV66617026; called by muse, varscan2
- ITSN1 | c.2439G>T p.V813= | Silent (SNP) | VAF 40/129 reads (31%) | catalogued as COSV66084202; called by muse, mutect2, varscan2
- LCT | c.3288C>T p.A1096= | Silent (SNP) | VAF 9/78 reads (12%) | catalogued as rs1364153635, COSV51550907; called by muse, mutect2, varscan2
- LRRC37A | c.4455C>T p.I1485= | Silent (SNP) | VAF 6/22 reads (27%) | called by mutect2, varscan2
- NBEAL2 | c.5886C>T p.I1962= | Silent (SNP) | VAF 76/243 reads (31%) | catalogued as rs765396438, COSV52760112; called by muse, mutect2, varscan2
- NCOR1 | c.2779C>T p.L927= | Silent (SNP) | VAF 20/51 reads (39%) | catalogued as COSV51982790; called by muse, mutect2, varscan2
- OR7A17 | c.441A>T p.A147= | Silent (SNP) | VAF 35/117 reads (30%) | catalogued as COSV59414653; called by muse, mutect2, varscan2
- P2RX1 | c.579C>T p.I193= | Silent (SNP) | VAF 23/67 reads (34%) | catalogued as COSV56654513; called by muse, varscan2
- PABPC5 | c.519C>T p.R173= | Silent (SNP) | VAF 19/88 reads (22%) | catalogued as COSV57041721; called by muse, mutect2, varscan2
- PCNT | c.3051G>A p.E1017= | Silent (SNP) | VAF 43/152 reads (28%) | catalogued as COSV64030104; called by muse, mutect2, varscan2
- SELL | c.321A>C p.I107= (on ENST00000650983; = p.I94= on NM_000655.5) | Silent (SNP) | VAF 11/41 reads (27%) | catalogued as COSV52552982, COSV99357666; called by muse, mutect2, varscan2
- SPAG4 | c.366G>C p.L122= | Silent (SNP) | VAF 12/15 reads (80%) | catalogued as COSV65330740; called by muse, mutect2, varscan2
- SPNS1 | c.297C>T p.L99= | Silent (SNP) | VAF 16/53 reads (30%) | catalogued as rs1426957851, COSV57955478; called by muse, mutect2, varscan2
- SPTAN1 | c.2916C>G p.V972= | Silent (SNP) | VAF 22/81 reads (27%) | catalogued as COSV63988211; called by muse, mutect2, varscan2
- TGIF2 | c.69G>A p.G23= | Silent (SNP) | VAF 96/170 reads (56%) | catalogued as rs1435396604, COSV65836639; called by muse, varscan2
- UPF1 | c.1753C>T p.L585= (on ENST00000599848 / NM_001297549.2; = p.L574= on NM_002911.4) | Silent (SNP) | VAF 17/45 reads (38%) | catalogued as COSV53198320; called by muse, mutect2, varscan2
- ZNF827 | c.1797G>A p.E599= | Silent (SNP) | VAF 14/98 reads (14%) | catalogued as rs1453849235, COSV65229060; called by muse, mutect2, varscan2
- AQP12B | c.123+18C>T | Intron (SNP) | VAF 10/33 reads (30%) | catalogued as rs1255128754, COSV68184140; called by muse, varscan2
- POLR3G | c.*45G>A | 3'UTR (SNP) | VAF 23/60 reads (38%) | catalogued as COSV67625676; called by muse, mutect2, varscan2
- TMEM99 | n.429C>T | RNA (SNP) | VAF 20/70 reads (29%) | catalogued as COSV56984154; called by muse, mutect2, varscan2
- TTN | c.10360+4459T>C | Intron (SNP) | VAF 44/156 reads (28%) | catalogued as COSV60167905; called by muse, mutect2, varscan2
